Somatic mutation profile of tumor specimen ALCH-B0EZ-TTP1-A (aliquot ALCH-B0EZ-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.9 years (25,547 days).
Specimen ALCH-B0EZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a5b426-af7a-4d3e-992d-855af0a937d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EZ-NB1-A (Blood Derived Normal), aliquot ALCH-B0EZ-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b62e5704-bc99-4977-adb2-cb30a4bfa501

The open-access MAF lists 186 somatic variants for this specimen: 118 protein-altering or splice-affecting, 38 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 38, Intron 15, Nonsense Mutation 12, 3'UTR 5, Frame Shift Del 3, RNA 3, Splice Site 3, 5'UTR 3, 5'Flank 3, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 162/338 reads (48%) | catalogued as rs137854577, CD106672, CM920028, COSV57367040; ClinVar: pathogenic; called by muse, varscan2
- ATM | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 163/335 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs730881359, CM122039, COSV53722454, COSV53722505; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 318/629 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP4 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1416355711, COSV54516825; called by mutect2, varscan2
- ACSM5 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as rs754696449; called by muse, mutect2, varscan2
- ADGRL3 | c.280C>G p.P94A (on ENST00000506720 / NM_001322402.2; = p.P26A on NM_015236.6) | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV72269947; called by muse, mutect2, varscan2
- ARFGEF1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs1439160507; called by muse, varscan2
- ATP8B4 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52725371; called by muse, varscan2
- CDH18 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 154/486 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1031926484, COSV56923155; called by muse, mutect2, varscan2
- CNTN1 | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 127/269 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as rs750576185; called by muse, mutect2, varscan2
- COL1A2 | c.1771C>A p.R591S | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV51955505; called by muse, mutect2, varscan2
- CTNNBL1 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 64/176 reads (36%) | catalogued as COSV63747623; called by muse, mutect2, varscan2
- CXXC5 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1210969453; called by muse, mutect2, varscan2
- EPHB4 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs775718656; called by muse, mutect2, varscan2
- EXOC3L1 | c.1723T>C p.W575R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1376104511; called by muse, mutect2, varscan2
- KCNMB2 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs946980945; called by muse, mutect2, varscan2
- KIAA1549 | c.4385C>T p.S1462L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752229213, COSV54321937; called by muse, mutect2, varscan2
- KRTAP13-1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.099); catalogued as rs368489202; called by muse, mutect2, varscan2
- MMP9 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs371340871, COSV63433763; called by muse, mutect2
- MYF5 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57355749; called by muse, mutect2, varscan2
- OR4C13 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 10/315 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs782771140; called by muse, mutect2
- OR56A1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs139301829; called by muse, mutect2
- OR8H2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV57945018; called by muse, mutect2, varscan2
- PCDHB16 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.047); catalogued as rs534146193; called by muse, mutect2, varscan2
- PPP1R26 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs201579051, COSV63356496; called by muse, mutect2, varscan2
- PPP2R2B | c.493C>T p.R165* (on ENST00000394409; = p.R231* on NM_181674.2) | Nonsense Mutation (SNP) | VAF 63/129 reads (49%) | catalogued as COSV60778987; called by muse, mutect2, varscan2
- PRR19 | c.874del p.V292* | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | catalogued as COSV56627770; called by mutect2, pindel, varscan2
- PSG8 | c.958C>A p.R320S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100126217; called by muse, mutect2, varscan2
- PTPRD | c.744G>T p.M248I | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV61929096; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs754457347; called by muse, mutect2, varscan2
- RASGRP2 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV62448815; called by muse, mutect2, varscan2
- SI | c.4441G>T p.V1481L | Missense Mutation (SNP) | VAF 130/515 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV52299905; called by muse, mutect2, varscan2
- SI | c.3674G>T p.G1225V | Missense Mutation (SNP) | VAF 141/522 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52284184; called by muse, mutect2, varscan2
- SLITRK1 | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 189/616 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.725); catalogued as rs755712979, COSV65674673; called by muse, mutect2, varscan2
- SPRED1 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 170/415 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1385820657; called by muse, mutect2, varscan2
- SUPT20HL1 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as rs1025772056; called by muse, mutect2, varscan2
- SVEP1 | c.9956C>A p.P3319H | Missense Mutation (SNP) | VAF 106/203 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV52842663; called by muse, mutect2, varscan2
- TMC2 | c.835-1G>T p.X279_splice | Splice Site (SNP) | VAF 32/127 reads (25%) | catalogued as COSV62650000; called by muse, varscan2
- TRPM2 | c.3619G>T p.A1207S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100307960, COSV100309585; called by muse, varscan2
- VGLL3 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV67353267; called by muse, varscan2
- ADAM22 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 131/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ADGRL3 | c.1804C>A p.L602I (on ENST00000506720 / NM_001322402.2; = p.L534I on NM_015236.6) | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- AKTIP | c.533T>G p.L178* | Nonsense Mutation (SNP) | VAF 43/207 reads (21%) | called by muse, mutect2, varscan2
- ANK2 | c.8102C>A p.S2701Y | Missense Mutation (SNP) | VAF 121/245 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATR | c.6977G>A p.C2326Y | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CDC42BPG | c.3823G>T p.G1275C | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN10 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- COL6A6 | c.3037C>A p.P1013T | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DENND5B | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- DHX36 | c.2243T>G p.L748W | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DRD5 | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DSEL | c.1854T>G p.D618E | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DVL3 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBL | c.757T>A p.F253I | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FSTL1 | c.863A>T p.Q288L | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GCSAM | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 176/493 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GPR101 | c.1401C>A p.D467E | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H3C6 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HYKK | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 112/297 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IGHV1-69 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- INSR | c.2993A>C p.E998A | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- JAKMIP1 | c.2307C>G p.I769M | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KIF6 | c.1778del p.G593Efs*4 | Frame Shift Del (DEL) | VAF 215/523 reads (41%) | called by mutect2, pindel, varscan2
- KLF5 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LEF1 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC7 | c.4428G>T p.R1476S (on ENST00000651989 / NM_001370785.2; = p.R1396S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MAGEB5 | c.108C>A p.C36* | Nonsense Mutation (SNP) | VAF 59/172 reads (34%) | called by muse, mutect2, varscan2
- MCUR1 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 145/343 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MMP2 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MUC17 | c.10418C>A p.S3473Y | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH8 | c.3656A>G p.K1219R | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- MYO18B | c.2617C>A p.H873N | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.5689C>T p.H1897Y | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYOM2 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NANOGNB | c.514A>T p.R172* | Nonsense Mutation (SNP) | VAF 40/171 reads (23%) | called by muse, mutect2, varscan2
- NBEA | c.4233+4A>T | Splice Region (SNP) | VAF 136/448 reads (30%) | called by muse, mutect2, varscan2
- NEDD4L | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFKBIZ | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR3C2 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.309); called by muse, mutect2
- OR4C46 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ORC4 | c.1040A>C p.Q347P | Missense Mutation (SNP) | VAF 131/450 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- OXCT1 | c.732+1G>T p.X244_splice | Splice Site (SNP) | VAF 94/396 reads (24%) | called by muse, mutect2, varscan2
- PA2G4 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 45/229 reads (20%) | called by muse, mutect2, varscan2
- PALD1 | c.2510G>C p.R837P | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFN2 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 30/431 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2
- PLD5 | c.730G>T p.G244* (on ENST00000442594; = p.G182* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1087A>T p.I363L | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PMS1 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- POLR3B | c.3067C>T p.R1023W | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRB2 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.139); called by muse, varscan2
- PRSS1 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PSMD9 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTH1R | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBFOX3 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RC3H1 | c.1937T>G p.L646R | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- REN | c.628T>G p.F210V | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF212 | c.550A>T p.S184C | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPS6KA6 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SCN3A | c.3467A>C p.E1156A | Missense Mutation (SNP) | VAF 58/726 reads (8%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.784); called by muse, mutect2
- SETBP1 | c.1711T>C p.Y571H | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGCG | c.317A>T p.Q106L | Missense Mutation (SNP) | VAF 152/474 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SIRPG | c.1007A>G p.Q336R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SIX3 | c.937del p.R313Afs*11 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1337T>A p.L446* | Nonsense Mutation (SNP) | VAF 44/167 reads (26%) | called by mutect2, varscan2
- STK32C | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- TEX101 | c.242G>A p.C81Y (on ENST00000598265 / NM_001130011.3; = p.C99Y on NM_031451.4) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX15 | c.3467G>A p.S1156N (on ENST00000256246; = p.S1539N on NM_001350162.2) | Missense Mutation (SNP) | VAF 117/345 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TMEM191C | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRDN | c.413T>A p.L138* | Nonsense Mutation (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- TRPA1 | c.1595T>C p.V532A | Missense Mutation (SNP) | VAF 41/609 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2
- UMPS | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- UNC79 | c.997G>T p.G333C (on ENST00000393151 / NM_001346218.2; = p.G156C on NM_020818.5) | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP17L2 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 142/529 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VPS13A | c.5415+1G>T p.X1805_splice | Splice Site (SNP) | VAF 103/241 reads (43%) | called by muse, varscan2
- ZNF24 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, mutect2
- ZNF559 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF573 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZNF688 | c.229dup p.W77Lfs*7 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- AP2M1 | c.171C>T p.H57= | Silent (SNP) | VAF 41/281 reads (15%) | catalogued as rs770792578; called by muse, mutect2, varscan2
- C11orf42 | c.33G>A p.L11= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as COSV60391965; called by muse, mutect2, varscan2
- CACNA1S | c.4071A>G p.A1357= | Silent (SNP) | VAF 77/404 reads (19%) | called by muse, mutect2, varscan2
- CCDC27 | c.1236G>T p.L412= | Silent (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- CETP | c.651A>G p.T217= | Silent (SNP) | VAF 65/271 reads (24%) | catalogued as rs754185945; called by muse, mutect2, varscan2
- CFH | c.1140G>A p.S380= | Silent (SNP) | VAF 22/718 reads (3%) | catalogued as rs1273044132, COSV62777808; called by muse, mutect2
- COL4A3 | c.273T>G p.G91= | Silent (SNP) | VAF 160/468 reads (34%) | called by muse, varscan2
- COL9A1 | c.2019T>C p.G673= | Silent (SNP) | VAF 30/621 reads (5%) | called by muse, mutect2
- DDX41 | c.105C>T p.P35= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs1344271042; called by muse, mutect2, varscan2
- FAM83B | c.1515A>G p.S505= | Silent (SNP) | VAF 111/483 reads (23%) | called by muse, mutect2, varscan2
- FBL | c.270G>T p.P90= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as rs369326013; called by muse, mutect2, varscan2
- FRY | c.5641C>T p.L1881= | Silent (SNP) | VAF 92/272 reads (34%) | catalogued as rs1218936274; called by muse, mutect2, varscan2
- FSIP2 | c.2193T>A p.A731= | Silent (SNP) | VAF 134/426 reads (31%) | called by muse, mutect2, varscan2
- GPR152 | c.939C>T p.F313= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs144851549; called by muse, mutect2, varscan2
- HTRA3 | c.1224C>T p.I408= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs375712905; called by muse, mutect2, varscan2
- KIR3DL1 | c.1248G>A p.Q416= | Silent (SNP) | VAF 136/262 reads (52%) | called by muse, mutect2, varscan2
- LIG1 | c.1710C>T p.D570= | Silent (SNP) | VAF 41/195 reads (21%) | catalogued as rs754148152, COSV54390043, COSV99619508; called by muse, mutect2, varscan2
- LPO | c.1662C>T p.N554= | Silent (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- MRPS18A | c.165G>A p.A55= | Silent (SNP) | VAF 105/275 reads (38%) | catalogued as rs140836863; called by muse, mutect2, varscan2
- MYH9 | c.1461G>T p.L487= | Silent (SNP) | VAF 109/309 reads (35%) | called by muse, mutect2, varscan2
- NEDD4 | c.774T>C p.I258= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- OR2T33 | c.258A>T p.G86= | Silent (SNP) | VAF 123/779 reads (16%) | called by muse, mutect2
- OR2T8 | c.258A>T p.G86= | Silent (SNP) | VAF 61/109 reads (56%) | called by muse, mutect2, varscan2
- OR8I2 | c.237T>G p.P79= | Silent (SNP) | VAF 59/180 reads (33%) | called by muse, mutect2, varscan2
- PDE1C | c.1311C>A p.P437= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as rs766220881, COSV58530005; called by muse, mutect2, varscan2
- PLD5 | c.729G>C p.L243= (on ENST00000442594; = p.L181= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100139742, COSV100141854; called by muse, mutect2, varscan2
- PRAMEF11 | c.804G>A p.K268= | Silent (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- RET | c.2976G>T p.P992= | Silent (SNP) | VAF 185/458 reads (40%) | called by muse, mutect2, varscan2
- RIPOR2 | c.846G>C p.V282= | Silent (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- RXFP3 | c.951C>T p.S317= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV57503848; called by muse, mutect2, varscan2
- SAGE1 | c.885C>A p.T295= | Silent (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- SELPLG | c.564C>T p.G188= | Silent (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- SNAP91 | c.909T>C p.S303= | Silent (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- STK32C | c.969G>A p.K323= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- TGDS | c.654G>A p.R218= | Silent (SNP) | VAF 27/242 reads (11%) | called by muse, mutect2, varscan2
- UNC5C | c.2607G>T p.L869= | Silent (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- ZNF703 | c.1704A>T p.G568= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- ZPLD1 | c.1173C>T p.C391= (on ENST00000466937 / NM_001329788.1; = p.C407= on NM_175056.2) | Silent (SNP) | VAF 82/277 reads (30%) | catalogued as rs776881701; called by muse, mutect2, varscan2
- AC008132.1 | chr22:18848067 C>A | 5'Flank (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-415G>T | Intron (SNP) | VAF 110/326 reads (34%) | catalogued as COSV68024424; called by muse, mutect2, varscan2
- ADGRL2 | c.3101+895A>G | Intron (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- AGMO | c.*7T>A | 3'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- AL021937.5 | n.49_50delinsA | RNA (DEL) | VAF 12/83 reads (14%) | called by pindel, varscan2*
- AL353804.4 | chrX:73823990 T>A | 5'Flank (SNP) | VAF 77/139 reads (55%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2449G>T | Intron (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- CRIP1 | c.-28T>G | 5'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- CYP19A1 | c.*210C>G | 3'UTR (SNP) | VAF 68/158 reads (43%) | called by muse, mutect2, varscan2
- DYSF | c.458-437G>T | Intron (SNP) | VAF 38/108 reads (35%) | called by muse, mutect2, varscan2
- FYB1 | c.*35G>T | 3'UTR (SNP) | VAF 56/169 reads (33%) | called by muse, mutect2, varscan2
- HYDIN | c.1738+3920C>A | Intron (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- KLK2 | chr19:50873431 C>A | 5'Flank (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.-14G>T | 5'UTR (SNP) | VAF 51/125 reads (41%) | catalogued as rs758303775; called by muse, mutect2, varscan2
- LINC01559 | n.217C>A | RNA (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2
- LINC02337 | chr13:111645192 G>T | 3'Flank (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- LSAMP | c.919+7251G>C | Intron (SNP) | VAF 49/139 reads (35%) | catalogued as rs1054695808; called by muse, mutect2, varscan2
- MBD3 | c.*5+11del | Intron (DEL) | VAF 16/62 reads (26%) | called by pindel, varscan2
- MLIP | c.613-11584G>T | Intron (SNP) | VAF 101/405 reads (25%) | catalogued as rs1457020245; called by muse, mutect2, varscan2
- MUC20P1 | n.1405T>C | RNA (SNP) | VAF 57/404 reads (14%) | called by muse, varscan2
- NRG1 | c.502+30972G>A | Intron (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91585C>A | Intron (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- PDHX | c.-22A>T | 5'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- SAG | c.806+23G>A | Intron (SNP) | VAF 30/126 reads (24%) | catalogued as rs571175750; called by muse, mutect2, varscan2
- SLC22A11 | c.*2A>G | 3'UTR (SNP) | VAF 59/174 reads (34%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3546+65C>T | Intron (SNP) | VAF 7/62 reads (11%) | catalogued as rs780821981; called by muse, mutect2, varscan2
- SV2C | c.581-20799G>A | Intron (SNP) | VAF 118/247 reads (48%) | catalogued as rs1364704166; called by muse, mutect2, varscan2
- TMEM232 | n.1012-9379G>C | Intron (SNP) | VAF 96/228 reads (42%) | called by muse, mutect2, varscan2
- TSPAN18 | c.-10-2987G>T | Intron (SNP) | VAF 40/129 reads (31%) | catalogued as COSV60884087; called by muse, mutect2, varscan2
- ZNF720 | c.*104G>T | 3'UTR (SNP) | VAF 97/273 reads (36%) | called by muse, mutect2, varscan2
